Somatic mutation profile of tumor specimen TCGA-OR-A5KU-01A (aliquot TCGA-OR-A5KU-01A-11D-A29I-10) from TCGA case TCGA-OR-A5KU, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 37.1 years (13,559 days).
Specimen TCGA-OR-A5KU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d393b17a-43e9-44fc-83c0-52e58b3951a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5KU-10A (Blood Derived Normal), aliquot TCGA-OR-A5KU-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c89b66f-d785-4911-bb40-bcb2126fbd32

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 8, Splice Region 1, Nonsense Mutation 1, In Frame Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 58/154 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- DEUP1 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 76/109 reads (70%) | catalogued as rs374648091, COSV53209665; called by muse, mutect2, varscan2
- DGKD | c.1214C>T p.P405L (on ENST00000264057 / NM_152879.3; = p.P361L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/126 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139149715; called by muse, mutect2, varscan2
- HTRA3 | c.903C>T p.N301= | Splice Region (SNP) | VAF 48/125 reads (38%) | catalogued as rs763506304; called by muse, mutect2, varscan2
- ITGAL | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs753378071; called by muse, mutect2, varscan2
- LGALS12 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs777943529; called by muse, mutect2, varscan2
- MATK | c.1264C>T p.R422W (on ENST00000310132 / NM_139355.3; = p.R423W on NM_002378.4) | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420878080, COSV59555207; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.50dup p.A18Gfs*6 | Frame Shift Ins (INS) | VAF 62/289 reads (21%) | called by mutect2, varscan2
- GALK2 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR1 | c.2515G>C p.E839Q (on ENST00000354582; = p.E824Q on NM_002222.7) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MINDY2 | c.1088T>C p.I363T | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OCRL | c.2243A>G p.Y748C | Missense Mutation (SNP) | VAF 53/268 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- RAB8A | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF84 | c.1515_1517del p.H505del | In Frame Del (DEL) | VAF 20/64 reads (31%) | called by pindel, varscan2
- AICDA | c.93C>T p.Y31= | Silent (SNP) | VAF 99/198 reads (50%) | catalogued as rs777729620, CM064965, COSV57563560; called by muse, mutect2, varscan2
- CCDC22 | c.165T>A p.P55= | Silent (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- EFHD1 | c.426C>T p.F142= | Silent (SNP) | VAF 66/84 reads (79%) | catalogued as rs776207789, COSV51132969; called by muse, mutect2, varscan2
- EGFLAM | c.2211C>T p.G737= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1163773501, COSV59292153; called by muse, mutect2
- PHLDB2 | c.1416C>T p.T472= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs112434778; called by muse, mutect2, varscan2
- PRSS22 | c.609C>T p.I203= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs1049497419, COSV50721019; called by muse, mutect2, varscan2
- SPAM1 | c.1242G>A p.K414= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- ZNF174 | c.489G>A p.P163= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs140705448; called by muse, mutect2, varscan2
- TSPEAR | c.83-33082A>G | Intron (SNP) | VAF 52/919 reads (6%) | called by muse, mutect2
